Surgical pathology report (de-identified scan), TCGA case TCGA-2A-AAYO, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Memorial Sloan Kettering Cancer Center, specimen TCGA-2A-AAYO-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

PSA 5.3, cT1c, 3+3 = 6, bilateral disease at apex and right mid

DATE OF TUMOR PROCUREMENT:

Specimens Submitted:

1: Prostate and seminal vesicles

DIAGNOSIS:

1. Prostate and seminal vesicles:

Part # 1

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:3

Total Gleason score:6

A minor component of Gleason pattern 4 also present

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: Prostate, NOS C61.9

hw
3/1/14

Tumor Location:

Involves Right anterior

Involves Left anterior

Dominant tumor mass located in: right and left anterior, apex and mid

Vascular Invasion:

Not Identified

Perineural Invasion:

Identified

Tumor Multicentricity:

Multicentric foci of invasive carcinoma are present

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Tumor invades into, but not beyond prostate capsule

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT2b (confined to the prostate & capsule, involving both lobes)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "Prostate and seminal vesicles". It consists of a prostate and seminal vesicles. The total weight is 69 grams. The prostate measures 4 cm from apex to base, 5.2 cm transversely, and 4.5 cm from anterior to posterior. The right and left seminal vesicles measure 4 x 1 and 4 x 1.3 cm, respectively. The external surface of the prostate is smooth. The prostate is inked (right=green, left=blue) and fixed in formalin overnight. The prostate is serially cut from apex to base at approximately 3-4 mm intervals. The prostate is entirely submitted.

Summary of Sections: RA-right apical margin, LA-left apical margin, BN-bladder neck margin

RSV-right seminal vesicle, LSV-left seminal vesicle, A-G -serial sections of prostate (apex to base)

Summary of Sections:

Part 1: Prostate and seminal vesicles

Blocks	Block Designation	PCs
1	A	1
1	B	1
1	BN	1
1	C	1
1	D	1
2	E	2
2	F	2
1	G	1
1	LA	1
1	LSV	1
1	RA	1
1	RSV	1

Criteria	W 1/15/14	Yes	No

Source: NCI Genomic Data Commons file 5a5f7354-fa72-436f-b7be-e5dfc604e409 (TCGA-2A-AAYO.3889AA76-F350-4DA4-987B-79E8D2349262.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).